Gene-level copy-number profile of tumor specimen TCGA-W5-AA2T-01A from TCGA case TCGA-W5-AA2T, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.5 years (23,560 days).
Specimen TCGA-W5-AA2T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.fd7543b9-1dc4-455e-916e-ffce01532ee7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA2T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ee97963-6da4-4cc3-9ff0-080bd8d7b0c6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 200; copy number 2: 16,558; copy number 3: 2,559; copy number 4: 34,888; copy number 5: 1,543; copy number 6: 3,866; copy number 7: 30; copy number 8: 47; copy number 48: 25; copy number 51: 4; copy number 54: 7; copy number 58: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA2T-01A-12D-A416-01): tumor purity 0.85, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–10,181,239, 81 genes (broad region; genes not listed).
- chr1:10,227,718–10,227,803, 1 gene: AL358013.1.
- chr4:177,728,757–178,028,971, 2 genes (within-gene range 0–2): LINC01098, LINC01099.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:153,067,278–153,377,562, 7 genes, copy number 58: HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2.
- chr11:68,980,021–69,775,341, 25 genes, copy number 48: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr11:78,171,249–78,418,348, 4 genes, copy number 51 (within-gene range 5–51): KCTD21, USP35, GAB2, AP002985.1.
- chr11:127,021,736–127,941,654, 7 genes, copy number 54 (within-gene range 4–54): AP001993.1, AP003121.1, LINC02712, RN7SKP121, RN7SKP279, AP003532.1, DNAJB6P1.

Autosomal genes at a single copy (total copy number 1): 138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
